TCGA case TCGA-EK-A2H0 — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c83c52f4-3815-4f49-8218-cf80aaa62e2f

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 24 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 24.4 years (8,918 days); Year of diagnosis: 2007; Method of diagnosis: Biopsy; FIGO stage: Stage IIB; FIGO staging edition year: 1995; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 54 days; Days to treatment end: 90 days; Treatment outcome: Complete Response; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 54 days; Days to treatment end: 112 days; Treatment dose: 4,500 cGy; Course number: 1; Number of fractions: 26; Treatment anatomic sites: Primary Tumor Field.

Follow-up (3 entries)
- Day 28 (preoperative): ECOG performance status: 0.
- Days to follow up: 1,398 days (3.8 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 1,847.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 88 kg; Height: 156 cm; BMI: 36.2.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Live Birth.

Exposures
- Exposure type: Tobacco.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EK-A2H0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 160 mg.
  Slide TCGA-EK-A2H0-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 94; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EK-A2H0-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 0; Total pregnancy count: 0; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Days to fdg or ct pet performed: 21.
- Follow-up form 1: Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Radiation adjuvant indicator: Yes; Brachytherapy type: HDR; Days to brachytherapy begin occurrence: 79; Days to brachytherapy end occurrence: 100; Brachytherapy total dose point a: 60; Brachytherapy status: Completed as planned; Radiation therapy xrt type: External beam radiation; Chemo concurrent dose: 385 mg/m2; Chemo concurrent course: Once weekly; Chemo concurrent fractions total: 6; New tumor event diagnosis indicator: No.
- Follow-up form 1, Radiation supplemental: Radiation therapy dose paraaortic nodes: 0; Radiation therapy status: Treatment not completed.
- Follow-up form 2: Lost to follow-up: No; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,847 days; disease-specific survival: no event (censored), 1,847 days; disease-free interval: no event (censored), 1,847 days; progression-free interval: no event (censored), 1,847 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EK-A2H0-01A-11D-A17U-01): tumor purity 0.73, ploidy 1.92, whole-genome doublings 0.
